Somatic mutation profile of tumor specimen TCGA-12-3646-01A (aliquot TCGA-12-3646-01A-01W-0922-08) from TCGA case TCGA-12-3646, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.8 years (21,855 days).
Specimen TCGA-12-3646-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 894bc34c-e381-4347-941e-d02019e2190e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-3646-10A (Blood Derived Normal), aliquot TCGA-12-3646-10A-01W-0922-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b0fed6aa-f40e-4092-a061-a8697dbb40db

The open-access MAF lists 80 somatic variants for this specimen: 63 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 16, Nonsense Mutation 6, Frame Shift Del 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GLDC | c.2311G>A p.G771R | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs386833553, CM061033, COSV58683845; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABI2 | c.710G>T p.R237I (on ENST00000295851 / NM_001375719.1; = p.R231I on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/532 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1464960082, COSV53694285; called by muse, mutect2
- ARMC5 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51657632, COSV99192346; called by muse, mutect2
- ATP1B4 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 68/182 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as rs773746224, COSV99486193; called by muse, mutect2, varscan2
- BCAS1 | c.1157C>T p.S386L | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.154); catalogued as COSV101006033; called by muse, mutect2, varscan2
- BMX | c.1967G>A p.R656H | Missense Mutation (SNP) | VAF 229/553 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1243725193, COSV99382586; called by muse, mutect2, varscan2
- C10orf90 | c.1451C>A p.P484H | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV99503251; called by muse, mutect2
- C7 | c.2525C>G p.T842S | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as COSV100495489, COSV57472381; called by muse, mutect2
- CALCR | c.1120G>A p.V374I (on ENST00000649521 / NM_001164737.2; = p.V358I on NM_001742.4) | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.014); catalogued as rs375960623; called by muse, mutect2, varscan2
- CAPN5 | c.734C>T p.A245V (on ENST00000456580; = p.A205V on NM_004055.5) | Missense Mutation (SNP) | VAF 183/377 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0.021); catalogued as COSV99581829; called by muse, mutect2, varscan2
- CASZ1 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV100680848; called by muse, mutect2, varscan2
- CFAP43 | c.1538G>A p.G513E | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1249742358, COSV53378241; called by mutect2, varscan2
- CFAP47 | c.1661G>A p.R554H | Missense Mutation (SNP) | VAF 133/243 reads (55%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs746688244, COSV52882671; called by muse, mutect2, varscan2
- CFP | c.469C>T p.R157W | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs745424947, COSV55950375; called by muse, mutect2, varscan2
- DBH | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.591); catalogued as COSV99707943; called by muse, mutect2, varscan2
- DCST1 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs373581735, COSV55061839; called by muse, mutect2, varscan2
- DOCK11 | c.6131C>T p.P2044L | Missense Mutation (SNP) | VAF 102/254 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV52247521; called by muse, mutect2, varscan2
- EYA3 | c.506G>T p.S169I | Missense Mutation (SNP) | VAF 64/580 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.431); catalogued as COSV100870222; called by muse, mutect2, varscan2
- FER1L6 | c.2299C>T p.R767* | Nonsense Mutation (SNP) | VAF 106/242 reads (44%) | catalogued as rs553419499, COSV67548308; called by muse, mutect2, varscan2
- FOLR3 | c.200C>T p.T67M | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as rs371900505; called by muse, mutect2, varscan2
- GIMAP7 | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 69/275 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs761959705, COSV57958744, COSV57960327; called by muse, mutect2, varscan2
- GPRC5D | c.226C>A p.L76I | Missense Mutation (SNP) | VAF 65/123 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); catalogued as COSV99964178; called by muse, mutect2, varscan2
- GRID2 | c.2621T>A p.L874Q | Missense Mutation (SNP) | VAF 109/202 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99938203; called by muse, mutect2, varscan2
- GUCA1C | c.67T>C p.Y23H | Missense Mutation (SNP) | VAF 30/253 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as COSV99225309; called by muse, mutect2, varscan2
- HDAC1 | c.107G>T p.R36L | Missense Mutation (SNP) | VAF 11/234 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101000329; called by muse, mutect2
- HHIPL2 | c.1853C>T p.T618I | Missense Mutation (SNP) | VAF 16/359 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV100596646; called by muse, mutect2
- IL23R | c.769T>C p.Y257H | Missense Mutation (SNP) | VAF 8/202 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as rs1490421226, COSV100724619; called by muse, mutect2
- IMPG2 | c.2287G>A p.V763I | Missense Mutation (SNP) | VAF 314/802 reads (39%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV99514942; called by muse, mutect2, varscan2
- ITGAM | c.2534G>A p.R845H (on ENST00000648685 / NM_001145808.2; = p.R844H on NM_000632.4) | Missense Mutation (SNP) | VAF 179/375 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as rs766088000, COSV54934811; called by muse, mutect2, varscan2
- KCNA4 | c.617A>C p.E206A | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV100068636; called by muse, mutect2, varscan2
- KRTAP10-12 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 98/196 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs782587806, COSV100552200; called by muse, mutect2, varscan2
- LAMC2 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 75/138 reads (54%) | SIFT tolerated (0.44); PolyPhen benign (0.054); catalogued as rs200275839, COSV51457897; called by muse, mutect2, varscan2
- LINGO2 | c.1343G>A p.R448Q | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs145524081; called by muse, mutect2, varscan2
- MAGEB6 | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 93/281 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs371772454, COSV66872903; called by muse, mutect2, varscan2
- MSL3 | c.1300G>A p.V434M (on ENST00000312196 / NM_078629.4; = p.V268M on NM_006800.4) | Missense Mutation (SNP) | VAF 105/118 reads (89%) | SIFT tolerated (0.52); PolyPhen benign (0.023); catalogued as rs757659444, COSV100384596; called by muse, mutect2, varscan2
- NCKAP1L | c.2648C>G p.S883C | Missense Mutation (SNP) | VAF 14/412 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); catalogued as COSV99514593, COSV99514675; called by muse, mutect2
- NGLY1 | c.848G>A p.C283Y | Missense Mutation (SNP) | VAF 35/595 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99770162; called by muse, mutect2
- NONO | c.685C>A p.Q229K | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV99338630; called by muse, mutect2, varscan2
- ODF2L | c.1151T>A p.L384H (on ENST00000317336; = p.L355H on NM_020729.3) | Missense Mutation (SNP) | VAF 51/102 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99643883; called by muse, mutect2, varscan2
- OPN1LW | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 377/607 reads (62%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.72); catalogued as COSV100885025; called by muse, mutect2, varscan2
- OR2Y1 | c.839T>C p.I280T | Missense Mutation (SNP) | VAF 166/349 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV100322676; called by muse, mutect2, varscan2
- OR5W2 | c.824C>G p.S275* | Nonsense Mutation (SNP) | VAF 28/77 reads (36%) | catalogued as COSV100747556, COSV104419262; called by muse, mutect2, varscan2
- PDIA3 | c.226G>A p.G76R | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.233); catalogued as COSV100294914, COSV104393826; called by muse, mutect2, varscan2
- PLCG2 | c.2857C>T p.R953* | Nonsense Mutation (SNP) | VAF 37/77 reads (48%) | catalogued as rs1278946830, COSV100842092; called by muse, mutect2, varscan2
- PRRC2C | c.5080C>T p.R1694C (on ENST00000367742; = p.R1692C on NM_015172.4) | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100144777; called by muse, mutect2, varscan2
- PRSS16 | c.1034A>T p.K345M | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.657); catalogued as COSV100041567; called by muse, mutect2, varscan2
- RALYL | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 126/293 reads (43%) | catalogued as COSV101569054; called by muse, mutect2, varscan2
- RB1CC1 | c.1876G>A p.D626N | Missense Mutation (SNP) | VAF 107/207 reads (52%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV99207148; called by muse, mutect2, varscan2
- RFX7 | c.1771C>T p.Q591* (on ENST00000559447 / NM_001368074.1; = p.Q688* on NM_022841.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 123/164 reads (75%) | catalogued as COSV100428270; called by muse, mutect2, varscan2
- SH2D4B | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 24/26 reads (92%) | SIFT tolerated (0.07); PolyPhen benign (0.069); catalogued as rs61861597, COSV99042937; called by muse, mutect2, varscan2
- SLAIN2 | c.961G>T p.A321S | Missense Mutation (SNP) | VAF 7/189 reads (4%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV99971519; called by muse, mutect2
- STAG2 | c.214G>A p.G72S | Missense Mutation (SNP) | VAF 155/425 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.776); catalogued as COSV99492509; called by muse, mutect2, varscan2
- SYNE1 | c.91C>T p.R31* | Nonsense Mutation (SNP) | VAF 66/130 reads (51%) | catalogued as rs199708211; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TCEAL4 | c.43C>A p.Q15K | Missense Mutation (SNP) | VAF 74/243 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.058); catalogued as COSV101010229; called by muse, mutect2, varscan2
- TSGA13 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs571780213, COSV63018295; called by muse, mutect2, varscan2
- TUBGCP6 | c.4681G>C p.V1561L | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.11); catalogued as COSV99954954; called by muse, mutect2
- VSTM2L | c.148A>T p.M50L | Missense Mutation (SNP) | VAF 316/759 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as COSV100991578; called by muse, mutect2, varscan2
- ZNF100 | c.1418C>A p.T473N | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.232); catalogued as COSV99973790; called by muse, mutect2
- ZNF226 | c.1886A>G p.N629S | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.201); catalogued as COSV100335032; called by muse, mutect2
- ZNF33B | c.401C>A p.P134H | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); catalogued as COSV100847617; called by muse, mutect2
- ZNF655 | c.1453A>G p.I485V | Missense Mutation (SNP) | VAF 41/228 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs773351523, COSV99401975; called by muse, mutect2, varscan2
- LRRN1 | c.902_914del p.V301Afs*38 | Frame Shift Del (DEL) | VAF 39/155 reads (25%) | called by mutect2, pindel, varscan2
- TTN | c.92979del p.Y30994Tfs*2 (on ENST00000591111; = p.Y23570Tfs*2 on NM_003319.4) | Frame Shift Del (DEL) | VAF 139/430 reads (32%) | called by mutect2, pindel, varscan2
- AHDC1 | c.4656G>T p.P1552= | Silent (SNP) | VAF 13/17 reads (76%) | catalogued as COSV55942591, COSV99898963; called by muse, mutect2, varscan2
- ARSF | c.1230C>A p.V410= | Silent (SNP) | VAF 94/177 reads (53%) | catalogued as COSV100839442; called by muse, mutect2, varscan2
- CAPN5 | c.969C>T p.R323= (on ENST00000456580; = p.R283= on NM_004055.5) | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV99581831; called by muse, mutect2
- CCDC151 | c.675C>T p.H225= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV100710457; called by muse, mutect2, varscan2
- DPPA2 | c.102C>T p.D34= | Silent (SNP) | VAF 93/194 reads (48%) | catalogued as rs572153453, COSV72117901; called by muse, mutect2, varscan2
- GML | c.444T>C p.F148= | Silent (SNP) | VAF 44/110 reads (40%) | catalogued as COSV99638124; called by muse, mutect2, varscan2
- GRID2 | c.2620C>T p.L874= | Silent (SNP) | VAF 107/197 reads (54%) | catalogued as COSV99938202; called by muse, mutect2, varscan2
- IMPA2 | c.525C>A p.G175= | Silent (SNP) | VAF 36/104 reads (35%) | catalogued as COSV52321184, COSV99302426; called by muse, mutect2, varscan2
- LCT | c.4365C>G p.R1455= | Silent (SNP) | VAF 26/115 reads (23%) | catalogued as COSV99928754, COSV99929366; called by muse, mutect2, varscan2
- LRRC32 | c.1227G>A p.L409= | Silent (SNP) | VAF 15/24 reads (63%) | catalogued as COSV99476723; called by muse, mutect2, varscan2
- NIPAL1 | c.1038T>C p.T346= | Silent (SNP) | VAF 26/53 reads (49%) | catalogued as COSV99784309; called by muse, mutect2, varscan2
- NPHS1 | c.3702C>T p.F1234= | Silent (SNP) | VAF 46/76 reads (61%) | catalogued as rs141375888; ClinVar: benign; called by muse, mutect2, varscan2
- OR2A7 | c.231G>A p.V77= | Silent (SNP) | VAF 68/540 reads (13%) | catalogued as COSV101512192, COSV101512234; called by muse, mutect2
- PPIG | c.363T>G p.G121= | Silent (SNP) | VAF 36/89 reads (40%) | catalogued as COSV99644224; called by muse, mutect2, varscan2
- PRKDC | c.684C>T p.S228= | Silent (SNP) | VAF 23/205 reads (11%) | catalogued as rs1340552587, COSV100038792; called by muse, mutect2, varscan2
- TRPM5 | c.2916C>T p.N972= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs775591280, COSV99329681; called by muse, mutect2, varscan2
- AC092718.9 | chr16:81156890 G>A | 3'Flank (SNP) | VAF 34/95 reads (36%) | catalogued as rs767856105; called by muse, mutect2, varscan2
